Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3968, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3968-01A (Primary Tumor).

Diagnosis:

Resected colon sample (sigma) with tumor-free oral and aboral resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria and without local lymph node metastases (G2, pT2, L0, V0, R0 pN0 0/19).

Source: NCI Genomic Data Commons file 12bbaa63-7b12-446e-94ec-29c7164fa9b6 (TCGA-AA-3968.4A17BB93-6880-4BEA-803B-A82FA1B5A9A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).